Somatic mutation profile of tumor specimen C3N-02694-02 (aliquot CPT0244890010) from CPTAC case C3N-02694, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 57.2 years (20,892 days).
Specimen C3N-02694-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7792c06d-7634-4174-9246-578b44e3b554.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02694-31 (Blood Derived Normal), aliquot CPT0244930002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51cfc2f5-fd7e-4a2d-801e-e7e48aa2c434

The open-access MAF lists 114 somatic variants for this specimen: 83 protein-altering or splice-affecting, 25 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 25, Nonsense Mutation 7, 5'UTR 2, 3'UTR 2, Splice Site 2, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs370686336; called by muse, mutect2, varscan2
- ARAF | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV51694819; called by muse, mutect2
- ATP8B1 | c.3073G>C p.D1025H | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV52173812; called by muse, mutect2
- CALHM2 | c.178G>C p.A60P | Missense Mutation (SNP) | VAF 94/741 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as COSV99588629; called by muse, mutect2, varscan2
- CFAP65 | c.1307G>A p.R436K | Missense Mutation (SNP) | VAF 19/480 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV55392337; called by muse, mutect2
- CHAC1 | c.596C>A p.A199E | Missense Mutation (SNP) | VAF 23/355 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs767919467; called by muse, mutect2
- CSMD2 | c.5185C>T p.R1729* | Nonsense Mutation (SNP) | VAF 17/285 reads (6%) | catalogued as COSV53915706; called by muse, mutect2
- ENTPD6 | c.1100G>C p.R367T | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as COSV61751281, COSV61752448; called by muse, mutect2
- F13A1 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1252588034, COSV53560817; called by muse, mutect2, varscan2
- GPRIN3 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 23/384 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs865984792; called by muse, mutect2
- HSPA2 | c.1414C>G p.R472G | Missense Mutation (SNP) | VAF 27/462 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV99904858; called by muse, mutect2
- KCNC1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56394922; called by muse, mutect2
- KCNH6 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148146561; called by muse, mutect2, varscan2
- KCNH7 | c.248C>A p.A83D | Missense Mutation (SNP) | VAF 13/402 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV59795753; called by muse, mutect2
- LINGO3 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 24/625 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.168); catalogued as rs1298484152; called by muse, mutect2
- MBD5 | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1219291357, COSV68696603; called by muse, mutect2
- MEF2B | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV50774362; called by muse, mutect2
- MIB2 | c.2680G>T p.E894* | Nonsense Mutation (SNP) | VAF 12/318 reads (4%) | catalogued as COSV61543588; called by muse, mutect2
- MON1B | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 21/329 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs745838166; called by muse, mutect2
- MROH5 | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV71301744; called by muse, mutect2
- MTG2 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 20/359 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs199831641; called by muse, mutect2
- OR2F2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs770609678, COSV68832847; called by muse, mutect2
- OR5H2 | c.622T>C p.S208P | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV62352205; called by muse, mutect2
- PDE4A | c.2087G>A p.R696K (on ENST00000380702 / NM_001111307.2; = p.R457K on NM_006202.3) | Missense Mutation (SNP) | VAF 42/528 reads (8%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as rs1163837248, COSV53350153; called by muse, mutect2
- PKHD1 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV61881644, COSV61891491; called by muse, mutect2
- PLB1 | c.2572G>A p.G858R | Missense Mutation (SNP) | VAF 29/335 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746817439, CM141398; called by muse, mutect2
- PTK2B | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.446); catalogued as COSV57751586, COSV57756601; called by muse, mutect2
- RYR1 | c.8554C>T p.R2852* | Nonsense Mutation (SNP) | VAF 16/402 reads (4%) | catalogued as rs886054396, CM123532, COSV62098357; ClinVar: uncertain significance; called by muse, mutect2
- RYR1 | c.12376G>C p.E4126Q | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV100616019, COSV62103813, COSV62114183; called by muse, mutect2
- SOBP | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.91); catalogued as rs370100152; called by muse, mutect2
- SORBS3 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs749475158, COSV53551663; called by muse, mutect2
- SOS2 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1364027643, COSV53567356; called by muse, mutect2
- SPATA25 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1258680353; called by muse, mutect2, varscan2
- SPEG | c.3701G>A p.R1234Q | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749872640; called by muse, mutect2
- TPST2 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.661); catalogued as rs762194832; called by muse, mutect2, varscan2
- VARS1 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs765817222; called by muse, mutect2
- XG | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as rs758797262; called by muse, mutect2, varscan2
- ZNF227 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100480453; called by muse, mutect2
- ZNF483 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 27/249 reads (11%) | catalogued as COSV100492717; called by muse, mutect2, varscan2
- ZNF536 | c.1511A>T p.E504V | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1568437494; called by muse, mutect2
- ACAD9 | c.139A>C p.K47Q | Missense Mutation (SNP) | VAF 66/651 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AMPH | c.449A>G p.H150R | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ARFGEF3 | c.138-1G>A p.X46_splice | Splice Site (SNP) | VAF 31/218 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP20 | c.3135G>C p.L1045F | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- ATP13A2 | c.1942C>G p.Q648E | Missense Mutation (SNP) | VAF 27/440 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.03); called by muse, mutect2
- ATP7A | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA2D1 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2
- CCDC86 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- DCLRE1A | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- DDN | c.350C>G p.S117W | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- FAM174C | c.212C>G p.T71R | Missense Mutation (SNP) | VAF 39/520 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- FHAD1 | c.1100A>T p.K367M | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- FRY | c.4315T>A p.W1439R | Missense Mutation (SNP) | VAF 37/392 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- HLA-DQB2 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- KCNC1 | c.317G>T p.W106L | Missense Mutation (SNP) | VAF 36/529 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KISS1R | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- LAMA4 | c.1574A>G p.E525G (on ENST00000230538 / NM_001105206.3; = p.E518G on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/435 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2
- LCLAT1 | c.1117T>C p.Y373H | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRC47 | c.1559C>G p.S520* | Nonsense Mutation (SNP) | VAF 26/394 reads (7%) | called by muse, mutect2
- MED12 | c.1743G>C p.L581= | Splice Region (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- MYH13 | c.3844G>A p.A1282T | Missense Mutation (SNP) | VAF 14/291 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.068); called by muse, mutect2
- NLGN3 | c.2509A>G p.T837A (on ENST00000358741 / NM_181303.2; = p.T817A on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); called by muse, varscan2
- NT5C2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- OR4D9 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- PBXIP1 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 10/308 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PKD1L3 | c.3775G>T p.A1259S | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); called by muse, mutect2
- SCFD1 | c.1159A>G p.S387G | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2
- SHD | c.298-1G>T p.X100_splice | Splice Site (SNP) | VAF 11/125 reads (9%) | called by muse, mutect2
- SIGLEC1 | c.4179C>A p.H1393Q | Missense Mutation (SNP) | VAF 31/560 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.018); called by muse, mutect2
- SIX4 | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- SLC12A3 | c.1505A>C p.N502T | Missense Mutation (SNP) | VAF 56/601 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2
- SLC38A10 | c.2894C>G p.S965C | Missense Mutation (SNP) | VAF 25/356 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2
- SSU72P8 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
- TADA2B | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.095); called by muse, mutect2
- TIGD3 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2
- TOM1L1 | c.1376T>G p.I459S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2
- TRIM66 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 21/405 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.34); called by muse, mutect2
- UNC79 | c.3766C>G p.P1256A (on ENST00000393151 / NM_001346218.2; = p.P1079A on NM_020818.5) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.254); called by muse, mutect2
- USP28 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2
- WDR81 | c.4050G>C p.Q1350H (on ENST00000409644 / NM_001163809.2; = p.Q299H on NM_152348.4) | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF385D | c.83A>G p.Q28R | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZNF483 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF483 | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSS2 | c.606G>C p.R202= | Silent (SNP) | VAF 23/293 reads (8%) | called by muse, mutect2
- ADRA1D | c.756G>A p.A252= | Silent (SNP) | VAF 34/331 reads (10%) | catalogued as rs769193684, COSV65240304; called by muse, mutect2, varscan2
- ATP1B3 | c.729G>A p.G243= | Silent (SNP) | VAF 12/153 reads (8%) | catalogued as rs181678148; called by muse, mutect2
- BMP3 | c.1308C>T p.C436= | Silent (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- CDKL2 | c.873A>T p.G291= | Silent (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- DCAF12L2 | c.60C>T p.A20= | Silent (SNP) | VAF 30/306 reads (10%) | catalogued as COSV100758665; called by muse, mutect2
- GRIN2A | c.3975C>T p.Y1325= | Silent (SNP) | VAF 24/275 reads (9%) | catalogued as rs545080350, COSV58022561; called by muse, mutect2
- GRM7 | c.159G>T p.G53= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs369829293; called by muse, mutect2
- HELZ2 | c.6183G>A p.E2061= (on ENST00000467148 / NM_001037335.2; = p.E1492= on NM_033405.3) | Silent (SNP) | VAF 29/548 reads (5%) | catalogued as rs1469064807; called by muse, mutect2
- ITGB4 | c.930G>T p.L310= | Silent (SNP) | VAF 16/309 reads (5%) | catalogued as COSV99563280; called by muse, mutect2
- MINAR1 | c.477G>T p.R159= | Silent (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- NEIL3 | c.1815C>T p.C605= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, varscan2
- ODC1 | c.1089C>T p.L363= | Silent (SNP) | VAF 28/536 reads (5%) | catalogued as rs376058087; called by muse, mutect2
- OR56B4 | c.480G>T p.L160= | Silent (SNP) | VAF 18/269 reads (7%) | called by muse, mutect2
- PROX1 | c.504G>C p.R168= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as COSV54779727; called by muse, mutect2, varscan2
- PTPN21 | c.2097G>A p.K699= | Silent (SNP) | VAF 21/514 reads (4%) | called by muse, mutect2
- RBMXL3 | c.2331C>G p.G777= | Silent (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- SEMA5B | c.2976C>G p.L992= | Silent (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- SLC2A9 | c.195C>T p.F65= | Silent (SNP) | VAF 29/452 reads (6%) | catalogued as rs1444569286; called by muse, mutect2
- SLC38A3 | c.1467C>T p.I489= | Silent (SNP) | VAF 42/469 reads (9%) | catalogued as rs1275943011; called by muse, mutect2
- SPATA31D1 | c.3921G>A p.G1307= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as COSV61199781; called by muse, mutect2
- TAAR1 | c.357T>C p.I119= | Silent (SNP) | VAF 32/303 reads (11%) | called by muse, mutect2, varscan2
- TMEM132E | c.2301G>A p.P767= (on ENST00000321639; = p.P857= on NM_001304438.2) | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- WDFY4 | c.2757G>A p.P919= | Silent (SNP) | VAF 36/506 reads (7%) | catalogued as rs1367184267; called by muse, mutect2
- ZNF536 | c.2634G>A p.S878= | Silent (SNP) | VAF 12/179 reads (7%) | catalogued as rs371143732; called by muse, mutect2
- GPR68 | c.-130+9227G>T | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- NFASC | c.-45A>G | 5'UTR (SNP) | VAF 58/359 reads (16%) | called by muse, mutect2, varscan2
- OSTM1 | c.*10A>G | 3'UTR (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- PDZRN4 | c.844-68501A>G | Intron (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- POLR1D | c.-15G>A | 5'UTR (SNP) | VAF 41/379 reads (11%) | called by muse, mutect2, varscan2
- TMEM68 | c.*20C>G | 3'UTR (SNP) | VAF 10/268 reads (4%) | called by muse, mutect2
